Somatic mutation profile of tumor specimen TCGA-DX-A8BK-01A (aliquot TCGA-DX-A8BK-01A-11D-A37C-09) from TCGA case TCGA-DX-A8BK, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 61.3 years (22,407 days).
Specimen TCGA-DX-A8BK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a65a184-8524-45a6-8ba9-018421956086.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A8BK-10A (Blood Derived Normal), aliquot TCGA-DX-A8BK-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5bc3465-e4b0-4964-b849-fd775377d747

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>C p.X187_splice | Splice Site (SNP) | VAF 22/33 reads (67%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP11A | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs779258751, COSV99370279; called by muse, mutect2, varscan2
- ATP13A2 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1375989957, COSV100454536; called by muse, mutect2, varscan2
- C5orf15 | c.652C>G p.H218D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99198367; called by mutect2, varscan2
- CALB1 | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.153); catalogued as COSV99618651; called by muse, mutect2, varscan2
- CSNK1G3 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100631884; called by muse, mutect2
- DOCK7 | c.1120A>G p.K374E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs776355049, COSV99226433; called by mutect2, varscan2
- DUOX2 | c.1569G>C p.R523S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV101199678, COSV101199928; called by muse, mutect2
- IRX4 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99182914; called by muse, mutect2, varscan2
- LCP2 | c.113A>T p.K38M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99253775; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs62040026, COSV99169939; called by muse, mutect2
- MPDZ | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs749650642, COSV59935778; called by muse, mutect2, varscan2
- MS4A2 | c.409A>G p.S137G | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99627608; called by mutect2, varscan2
- NOP2 | c.1004T>A p.L335Q (on ENST00000322166 / NM_001258308.2; = p.L331Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100445313; called by mutect2, varscan2
- SCN2A | c.5704C>T p.R1902C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367833365, CM034570; called by mutect2, varscan2
- SLC6A9 | c.1660C>T p.R554W (on ENST00000360584 / NM_201649.4; = p.R500W on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs755142891, COSV62212030; called by muse, mutect2, varscan2
- TMEM108 | c.1517G>A p.S506N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100419757; called by mutect2, varscan2
- TTK | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100036701; called by muse, mutect2, varscan2
- ZZZ3 | c.2544T>A p.D848E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100890480; called by muse, mutect2, varscan2
- PKNOX1 | c.268_280del p.D90Kfs*4 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- DUOX2 | c.2784G>T p.L928= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV101199926; called by muse, mutect2, varscan2
- HPN | c.525G>A p.P175= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs35890010; called by muse, mutect2, varscan2
- PPARG | c.1182C>G p.P394= (on ENST00000287820 / NM_015869.5; = p.P364= on NM_005037.7) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99826898; called by mutect2, varscan2
- RIMBP2 | c.1683C>T p.G561= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs937313128, COSV55472692; called by muse, varscan2
- SYT3 | c.133C>A p.R45= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV58897613; called by mutect2, varscan2
- VIRMA | c.84G>T p.V28= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99889791; called by mutect2, varscan2
